MMRF case MMRF_1413 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9153e4c2-37e9-4cc3-83a8-14d2cedaa819

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,137 days); ISS stage: III; Days to last known disease status: 1,380 days (3.8 years); Days to last follow up: 1,380 days (3.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 101 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 128 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.932 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.07 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 67.2 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 11.4 µg/mL; Lactate Dehydrogenase 5.57 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 32 g/L; Total Protein 11.2 g/dL; Glucose 5.67 mmol/L.
- Day 78 (ECOG 1): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 3.39 g/L; Immunoglobulin A 5.58 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 7.57 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 5.5 mmol/L.
- Day 171 (ECOG 1): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 283 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 6.44 mmol/L.
- Day 416 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.98 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.27 mmol/L.
- Day 508 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.98 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 598 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 700 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 10.5 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 792 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.058 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.38 mg/dL; Immunoglobulin G 8.02 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 1.13 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 10.2 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 39.1 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 890 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 10.5 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.
- Day 996 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 8.99 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.83 mmol/L.
- Day 1,093 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.05 mmol/L.
- Day 1,194 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 9.84 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 1,275 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 6.11 mmol/L.
- Day 1,380 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 2.87 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 6.88 mmol/L.

Other clinical attributes
- Day 1: Weight: 97 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1413_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1413_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
